Somatic mutation profile of tumor specimen TCGA-DQ-7596-01A (aliquot TCGA-DQ-7596-01A-11D-2229-08) from TCGA case TCGA-DQ-7596, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G4; Age at diagnosis: 48.9 years (17,846 days).
Specimen TCGA-DQ-7596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e47c9e7-b379-46a5-9539-fc595c818f59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-7596-10D (Blood Derived Normal), aliquot TCGA-DQ-7596-10D-01D-2229-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb09aa3d-616a-4c65-95b2-c9d7395300bd

The open-access MAF lists 30 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs150325490; called by muse, mutect2, varscan2
- AFAP1L1 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99696202; called by muse, mutect2
- AGK | c.480G>C p.L160F | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.733); catalogued as COSV100814741; called by muse, mutect2
- ASXL1 | c.2767G>C p.E923Q | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.17); catalogued as COSV100041640; called by muse, mutect2
- CD1E | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100937087; called by muse, mutect2
- CEACAM7 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs201544117, COSV50072591; called by muse, mutect2
- CHRAC1 | c.275-1G>A p.X92_splice | Splice Site (SNP) | VAF 7/106 reads (7%) | catalogued as COSV55270388, COSV99636308; called by muse, mutect2
- DAPK1 | c.3389G>A p.R1130H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1411904981, COSV63783899; called by muse, mutect2
- DEF8 | c.571G>A p.E191K (on ENST00000268676 / NM_207514.3; = p.E130K on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.376); catalogued as rs1356591725, COSV99240820; called by muse, mutect2
- FKBP9 | c.831T>G p.S277R | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.435); catalogued as COSV99640611; called by muse, mutect2
- FRYL | c.8079G>C p.Q2693H | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51963073; called by muse, mutect2
- HUWE1 | c.12212G>A p.R4071Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99474725; called by muse, mutect2, varscan2
- KLRG2 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765088717, COSV100572614; called by muse, mutect2, varscan2
- NCOA2 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV101476069; called by muse, mutect2, varscan2
- NOD1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.996); catalogued as COSV56114967, COSV99768580; called by muse, mutect2
- OSBPL8 | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99675729; called by muse, mutect2
- PRDM2 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV99342895; called by muse, mutect2
- SPG11 | c.6338C>G p.S2113C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99969817; called by muse, varscan2
- TBC1D3F | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 10/351 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1243146216; called by muse, mutect2
- TLR5 | c.602T>A p.F201Y | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100643418; called by muse, mutect2, varscan2
- TMEM63A | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 4/84 reads (5%) | catalogued as COSV64763274; called by muse, mutect2
- TRIO | c.8608G>C p.E2870Q | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100702767; called by muse, mutect2
- ZNF99 | c.2156C>T p.T719I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.718); catalogued as COSV101233997, COSV68056149; called by muse, mutect2, varscan2
- ZXDC | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs960674822, COSV60446856; called by muse, mutect2, varscan2
- PIK3R1 | c.1718_1722del p.L573Qfs*27 (on ENST00000521381 / NM_181523.3; = p.L303Qfs*27 on NM_181504.4) | Frame Shift Del (DEL) | VAF 15/125 reads (12%) | called by mutect2, pindel, varscan2
- ATP10B | c.4269C>T p.S1423= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as rs112214351, COSV59150095; called by muse, mutect2, varscan2
- ENPP1 | c.825C>T p.I275= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs369580462; called by muse, mutect2, varscan2
- PTPN3 | c.1929C>T p.S643= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as rs1045299050, COSV52702102; called by muse, mutect2
- TNKS1BP1 | c.3504G>A p.R1168= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV100836321; called by muse, mutect2
